Gene-level copy-number profile of tumor specimen TCGA-VQ-A8PJ-01A from TCGA case TCGA-VQ-A8PJ, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 53.1 years (19,390 days).
Specimen TCGA-VQ-A8PJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.ae32eeeb-2ce7-46fc-b51e-b02db0949f1a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-A8PJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a84e91e5-ca67-433e-a3ad-9b535b990028

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 124; copy number 1: 13; copy number 2: 374; copy number 3: 14,692; copy number 4: 12,656; copy number 5: 7,600; copy number 6: 13,593; copy number 7: 2,630; copy number 8: 3,807; copy number 9: 3,746; copy number 10: 442; copy number 11: 41; copy number 12: 6; copy number 13: 23; copy number 14: 49; copy number 19: 8; copy number 58: 10; copy number 78: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-A8PJ-01A-11D-A40Z-01): tumor purity 0.61, ploidy 4.54, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 124 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,178,589–31,645,160, 124 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 10,767 genes in 46 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 7–10 (broad region; genes not listed).
- chr2:172,099,438–172,556,596, 10 genes, copy number 7 (within-gene range 5–7): DLX2, DLX2-DT, AC104088.1, AC104088.3, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1.
- chr3:96,753,185–198,222,513, 1,776 genes, copy number 8–11 (within-gene range 1–11) (broad region; genes not listed).
- chr4:139,495,941–139,740,745, 8 genes, copy number 7: SETD7, FTH1P24, AC112236.2, AC112236.3, AC112236.1, MGST2, RN7SKP237, H3P16.
- chr4:139,763,080–139,794,433, 2 genes, copy number 7: AC108053.1, RN7SKP253.
- chr6:52,576,787–53,061,824, 22 genes, copy number 10 (within-gene range 6–10): TRAM2-AS1, AL109918.2, AL109918.1, TMEM14A, GSTA8P, SREK1IP1P2, GSTA7P, GSTA2, GSTA12P, GSTA1, GSTA6P, GSTA5, GSTA11P, GSTA10P, GSTA3, GSTA9P, AL121969.1, GSTA4, 7SK, RN7SK, CILK1, AL031178.1.
- chr6:56,945,730–65,707,226, 63 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:70,972–27,152,581, 445 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr7:55,656,768–75,986,855, 482 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:150,584–62,249,879, 1,190 genes, copy number 8–10 (broad region; genes not listed).
- chr8:62,473,217–62,483,811, 2 genes, copy number 9: AC018861.2, AC018861.1.
- chr8:102,805,517–103,073,051, 10 genes, copy number 9 (within-gene range 6–9): GASAL1, AZIN1, AP003696.1, MAILR, AP003354.1, RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1.
- chr9:32,293,558–37,120,446, 207 genes, copy number 7–14 (broad region; genes not listed).
- chr10:61,662,929–62,096,944, 4 genes, copy number 10 (within-gene range 5–10): CABCOCO1, AL451049.1, LINC02625, ARID5B.
- chr10:86,395,187–86,631,628, 6 genes, copy number 10: AL844892.2, AL844892.1, WAPL, RNU6-780P, AL731569.1, RPL7AP8.
- chr10:86,935,540–87,191,465, 19 genes, copy number 14 (within-gene range 4–14): MMRN2, AC025268.1, SNCG, ADIRF-AS1, ADIRF, AL136982.7, AGAP11, BMS1P3, AL136982.1, AL136982.6, AL136982.4, AL136982.2, FAM25A, AL136982.5, RNU6-529P, GLUD1, SHLD2, AL136982.3, RN7SL733P.
- chr11:74,454,841–74,746,114, 14 genes, copy number 11–19: KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3, RANP3, RN7SKP297, CHRDL2, AP001324.3, MIR4696, AP001324.2, AP001324.1.
- chr12:109,445,410–109,888,467, 15 genes, copy number 8: AC007570.1, KCTD10, UBE3B, MMAB, RNU4-32P, MVK, RN7SKP250, FAM222A, FAM222A-AS1, TRPV4, MIR4497, GLTP, AC007834.2, RN7SL441P, AC007834.1.
- chr13:18,467,172–29,505,947, 268 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr13:31,199,975–67,230,445, 502 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr13:70,923,664–107,933,503, 422 genes, copy number 7–11 (broad region; genes not listed).
- chr14:102,770,040–102,933,596, 4 genes, copy number 13: AL132801.1, TRAF3, RNU6-1316P, AMN.
- chr17:26,981,694–27,170,310, 7 genes, copy number 7: AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.2.
- chr17:39,200,283–41,823,213, 160 genes, copy number 7–78 (broad region; genes not listed).
- chr17:47,409,322–48,866,522, 75 genes, copy number 8–9 (broad region; genes not listed).
- chr17:48,880,840–48,881,316, 2 genes, copy number 9: AC068531.1, AC068531.2.
- chr17:53,681,630–54,478,168, 5 genes, copy number 9: AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3.
- chr17:65,457,541–65,641,033, 3 genes, copy number 8: LINC02563, AXIN2, AC004805.1.
- chr17:65,644,308–65,655,395, 2 genes, copy number 8: AC004805.3, AC004805.2.
- chr17:68,793,549–78,360,077, 279 genes, copy number 7–14 (broad region; genes not listed).
- chr17:79,089,345–81,721,016, 102 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr18:20,946,906–22,098,780, 30 genes, copy number 7–10: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1.
- chr19:10,391,133–10,713,437, 17 genes, copy number 8: CDC37, MIR1181, PDE4A, KEAP1, AC011461.1, S1PR5, ATG4D, RNU7-140P, MIR1238, KRI1, CDKN2D, AP1M2, AC011475.1, SLC44A2, ILF3-DT, ILF3, QTRT1.
- chr19:13,099,033–15,498,956, 109 genes, copy number 8 (broad region; genes not listed).
- chr19:47,581,023–47,886,315, 18 genes, copy number 13: RN7SL322P, AC010519.1, AC010331.1, BICRA, BICRA-AS1, AC008985.1, EHD2, NOP53, SNORD23, NOP53-AS1, SELENOW, RPL23AP80, AC008745.1, TPRX1, CRX, TPRX2P, LINC01595, SULT2A1.
- chr19:54,868,939–58,605,223, 270 genes, copy number 9 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 8–11 (broad region; genes not listed).
- chr21:20,651,450–25,057,746, 41 genes, copy number 8 (within-gene range 5–8): LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1, AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684, LINC01692, AP000402.1, AP000146.1.
- chr21:41,441,056–41,582,887, 6 genes, copy number 9 (within-gene range 5–9): AP001610.2, TMPRSS2, AP001610.1, AP001610.3, AP006748.1, PCSEAT.
- chr22:15,290,718–17,779,481, 102 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
